Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046466-09A.2 (aliquot TARGET-15-SJMPAL046466-09A.2-01D) from TARGET case TARGET-15-SJMPAL046466, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (851 days).
Specimen TARGET-15-SJMPAL046466-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 026f97e4-77f1-4ddf-8e6f-12c3a0c252b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046466-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046466-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f32af0e-3393-4e5b-9611-09f6bd3975a1

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); called by mutect2, varscan2
- IGKV3D-20 | chr2:90039479 TC>GGG | Missense Mutation (INS) | VAF 7/67 reads (10%) | called by pindel, varscan2*
- IPO11 | c.1004C>A p.P335Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- KCTD3 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- MBIP | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2
- PKDREJ | c.6403G>T p.A2135S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR3 | c.10155C>A p.D3385E (on ENST00000389232; = p.D3386E on NM_001036.6) | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.797); called by muse, mutect2
- ZFHX3 | c.2778G>T p.E926D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.014); called by muse, mutect2
- ZNF536 | c.3340C>A p.Q1114K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.095); called by muse, mutect2
- ADGRD1 | c.2619C>A p.A873= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs903184478; called by muse, mutect2
- CNKSR3 | c.1245G>T p.L415= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs981082581; called by muse, mutect2
- POLD2 | c.195G>T p.L65= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- SLC25A24 | c.1227G>T p.V409= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- TMEM232 | c.927G>T p.L309= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
